Somatic mutation profile of tumor specimen MP2PRT-PATLKV-TBP1-A (aliquot MP2PRT-PATLKV-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATLKV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,865 days).
Specimen MP2PRT-PATLKV-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb8aa69a-5deb-4fb7-a4d7-6de38a486969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLKV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLKV-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7fe82e7-3478-459e-b132-23d014d14a50

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 18, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746906001; called by muse, mutect2, varscan2
- FNBP1L | c.1210C>T p.R404C (on ENST00000271234 / NM_001164473.2; = p.R346C on NM_017737.5) | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775850567; called by muse, mutect2, varscan2
- GGH | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs146984806; called by muse, mutect2, varscan2
- GZMB | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs767220668, COSV99362144; called by muse, mutect2, varscan2
- PTPRN2 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 117/517 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs764331168; called by muse, mutect2, varscan2
- VSTM2L | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 115/450 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs377435668; called by muse, mutect2, varscan2
- ADARB2 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 153/589 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C4orf54 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 77/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- DNAH11 | c.6659C>T p.A2220V | Missense Mutation (SNP) | VAF 73/355 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DNAH8 | c.12175A>G p.T4059A | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ERAS | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 138/1074 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- HOXD3 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 124/515 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE4DIP | c.4337C>G p.S1446C | Missense Mutation (SNP) | VAF 81/496 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RFPL4A | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 90/608 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN2A | c.5616G>A p.M1872I | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TPMT | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.315); called by muse, mutect2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 96/413 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF532 | c.2993A>G p.N998S | Missense Mutation (SNP) | VAF 89/445 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM167A | c.438C>T p.G146= | Silent (SNP) | VAF 112/413 reads (27%) | catalogued as rs761556428, COSV52670437; called by muse, mutect2, varscan2
- MAB21L4 | c.1200C>A p.A400= (on ENST00000388934 / NM_001085437.3; = p.A232= on NM_024861.4) | Silent (SNP) | VAF 129/496 reads (26%) | catalogued as rs138648049; called by muse, mutect2, varscan2
- SPTBN4 | c.3483C>T p.G1161= | Silent (SNP) | VAF 155/559 reads (28%) | catalogued as rs1159849490; called by muse, mutect2, varscan2
